Somatic mutation profile of tumor specimen C3N-02248-72 (aliquot CPT0129170007) from CPTAC case C3N-02248, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-02248-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf01620-5a88-4357-baa7-113bfe80e14f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02248-31 (Blood Derived Normal), aliquot CPT0130830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d31d93b0-d54e-445f-89b1-66aa9915c615

The open-access MAF lists 89 somatic variants for this specimen: 62 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 12, Intron 6, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 3, 3'UTR 3, RNA 2, 5'UTR 2, 5'Flank 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAR3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1220465171; called by muse, mutect2, varscan2
- C10orf90 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV52955793; called by muse, mutect2, varscan2
- CACNA1F | c.4427G>A p.R1476H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs868968074; called by muse, mutect2, varscan2
- COL5A2 | c.1574G>C p.G525A | Missense Mutation (SNP) | VAF 16/569 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100880570; called by muse, mutect2
- FAM124B | c.643T>A p.L215I | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310924673; called by muse, mutect2, varscan2
- IL22RA2 | c.471A>C p.E157D | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as rs772753982; called by muse, mutect2, varscan2
- MTOR | c.5917A>T p.I1973F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63873321; called by muse, mutect2
- NBEAL1 | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71375465; called by muse, mutect2, varscan2
- NUTM2B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 65/504 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.783); catalogued as rs751260029; called by mutect2, varscan2
- OLFML2B | c.1993C>G p.R665G | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99038674, COSV99668646; called by muse, mutect2, varscan2
- PCDHA4 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 15/487 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1554123909, COSV63539780; called by muse, mutect2
- PCDHGA12 | c.955del p.V319Cfs*16 | Frame Shift Del (DEL) | VAF 48/249 reads (19%) | catalogued as COSV52759587; called by mutect2, pindel, varscan2
- RIMS2 | c.3185G>A p.R1062K (on ENST00000666250 / NM_001348490.2; = p.R870K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as rs542594833; called by muse, mutect2, varscan2
- RYR2 | c.6280G>A p.G2094S | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.87); catalogued as rs777365708, COSV63682997; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.73261G>A p.E24421K (on ENST00000591111; = p.E16997K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/197 reads (20%) | PolyPhen probably damaging (0.994); catalogued as CM1514598; called by muse, mutect2, varscan2
- UGT2B4 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59319802; called by muse, mutect2, varscan2
- ZFP28 | c.1553T>C p.I518T | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.681); catalogued as rs1206469817; called by muse, mutect2, varscan2
- CAGE1 | c.592G>T p.G198* (on ENST00000512086; = p.G62* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- CILP2 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CNTN1 | c.2042T>A p.V681E | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPXM2 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CYP27B1 | c.1276A>T p.N426Y | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DNAH14 | c.238_243del p.P80_R81del | In Frame Del (DEL) | VAF 19/159 reads (12%) | called by mutect2, pindel
- ECT2 | c.1979G>C p.G660A (on ENST00000392692 / NM_001349098.2; = p.G629A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EHMT1 | c.2774T>A p.L925Q | Missense Mutation (SNP) | VAF 82/545 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EHMT2 | c.2183A>G p.N728S | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- FAM111A | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- FAM47C | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by mutect2, varscan2
- FANCI | c.2360A>T p.E787V | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HEPACAM | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 77/767 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IL17RA | c.2355G>C p.E785D | Missense Mutation (SNP) | VAF 117/965 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KRT222 | c.614dup p.N205Kfs*6 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- MACF1 | c.13759T>C p.S4587P (on ENST00000372915; = p.S2520P on NM_012090.5) | Missense Mutation (SNP) | VAF 60/497 reads (12%) | called by muse, mutect2, varscan2
- MACROD1 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.114); called by muse, mutect2
- MANEA | c.8del p.K3Sfs*20 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- MEI1 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MICA | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MICAL2 | c.2784+2T>C p.X928_splice | Splice Site (SNP) | VAF 63/245 reads (26%) | called by muse, mutect2, varscan2
- MME | c.1779T>G p.N593K | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MVB12A | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NPIPB15 | c.920del p.P307Hfs*13 | Frame Shift Del (DEL) | VAF 190/1860 reads (10%) | called by mutect2, pindel, varscan2
- NUP205 | c.4935A>C p.V1645= | Splice Region (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- OR2K2 | c.500G>T p.R167M (on ENST00000374428; = p.R138M on NM_205859.2) | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- PBRM1 | c.1281_1282del p.S429Tfs*14 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKG2 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PNPLA6 | c.2966+2T>A p.X989_splice (on ENST00000414982 / NM_001166111.2; = p.X941_splice on NM_006702.5) | Splice Site (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1301T>G p.V434G | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PNPLA8 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PRSS16 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2
- PXDN | c.203A>C p.D68A | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REV3L | c.7942T>A p.F2648I | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RPRD2 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SHANK2 | c.3101T>C p.I1034T | Missense Mutation (SNP) | VAF 239/976 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SI | c.1846A>G p.I616V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SRSF1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- SURF4 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 111/412 reads (27%) | called by muse, mutect2, varscan2
- TCL1A | c.337_*3del | Nonstop Mutation (DEL) | VAF 40/198 reads (20%) | called by pindel, varscan2
- TFPI | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- TMEM190 | c.484del p.E162Kfs*? | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- USP21 | c.1050-2A>G p.X350_splice | Splice Site (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- ZNF596 | c.587A>C p.E196A | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ABCA3 | c.1596C>T p.I532= | Silent (SNP) | VAF 46/472 reads (10%) | called by muse, mutect2
- ADAMTS3 | c.1149C>G p.T383= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as rs1334850380; called by muse, mutect2
- ATM | c.4122T>G p.P1374= | Silent (SNP) | VAF 57/247 reads (23%) | called by muse, mutect2, varscan2
- FAM98C | c.300G>A p.G100= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs1402372079; called by muse, mutect2
- LIMK1 | c.582G>A p.E194= | Silent (SNP) | VAF 106/296 reads (36%) | called by muse, mutect2, varscan2
- LRP1B | c.3666A>G p.L1222= | Silent (SNP) | VAF 71/346 reads (21%) | catalogued as rs770441116; called by muse, mutect2, varscan2
- PHKG2 | c.450G>C p.V150= | Silent (SNP) | VAF 15/410 reads (4%) | called by muse, mutect2
- PMEPA1 | c.774G>T p.G258= | Silent (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
- PRR36 | c.1933C>A p.R645= | Silent (SNP) | VAF 98/385 reads (25%) | catalogued as rs1016441321; called by muse, mutect2
- SAMD9L | c.3771A>G p.L1257= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as COSV59084104; called by muse, mutect2, varscan2
- SH3RF1 | c.1128T>C p.T376= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- UGGT1 | c.4137T>A p.P1379= | Silent (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- AQP2 | c.-31C>G | 5'UTR (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- CCDC110 | c.2461+845C>G | Intron (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- CMAHP | n.1491A>C | RNA (SNP) | VAF 44/166 reads (27%) | called by muse, mutect2, varscan2
- DOCK5 | c.168+1972A>T | Intron (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- GALT | c.821-20G>A | Intron (SNP) | VAF 105/805 reads (13%) | catalogued as COSV100535421; called by muse, mutect2, varscan2
- GPATCH8 | c.*465G>A | 3'UTR (SNP) | VAF 39/304 reads (13%) | called by muse, mutect2, varscan2
- GPHN | chr14:66505311 T>C | 5'Flank (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- KCTD15 | c.*376G>T | 3'UTR (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- KCTD15 | c.*377G>T | 3'UTR (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- KRT17P1 | n.700G>A | RNA (SNP) | VAF 104/594 reads (18%) | called by muse, mutect2, varscan2
- TGFB3 | c.516+35G>A | Intron (SNP) | VAF 53/290 reads (18%) | catalogued as rs562495124; called by muse, mutect2, varscan2
- TMEM237 | c.42+740A>T | Intron (SNP) | VAF 70/318 reads (22%) | called by muse, mutect2, varscan2
- TSSC2 | n.288-5607G>A | Intron (SNP) | VAF 132/640 reads (21%) | called by muse, mutect2, varscan2
- USP22 | chr17:21043633 G>T | 5'Flank (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- WAPL | c.-289C>T | 5'UTR (SNP) | VAF 83/371 reads (22%) | called by muse, mutect2, varscan2
